Somatic mutation profile of tumor specimen HCM-CSHL-0153-C50-01B (aliquot HCM-CSHL-0153-C50-01B-02D-A82H-36) from HCMI case HCM-CSHL-0153-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 62.7 years (22,886 days).
Specimen HCM-CSHL-0153-C50-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0314d961-2e7b-47a1-bbb0-26f260e9e015.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0153-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0153-C50-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/188fc80c-40c9-4ac7-adf0-3553150d4978

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 24, Silent 8, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 181/903 reads (20%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.3149C>T p.T1050M | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs916677846; called by muse, mutect2
- CHST11 | c.923C>A p.T308K | Missense Mutation (SNP) | VAF 16/530 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.429); catalogued as COSV100358873; called by muse, mutect2
- DENND4A | c.5546C>T p.T1849I | Missense Mutation (SNP) | VAF 44/949 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs750575447; called by muse, mutect2
- DISP2 | c.3152G>A p.R1051H | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1268388389, COSV99140760; called by muse, varscan2
- DOCK1 | c.1265G>A p.G422D | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757225154; called by muse, mutect2, varscan2
- GIGYF2 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 58/471 reads (12%) | catalogued as COSV65249910; called by muse, mutect2, varscan2
- HIPK2 | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 63/390 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as rs745902293; called by muse, mutect2, varscan2
- HMCN1 | c.4405C>T p.R1469C | Missense Mutation (SNP) | VAF 104/1300 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as rs140363573; called by muse, mutect2
- ICE1 | c.595A>T p.I199L | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as rs993126874, COSV56819206, COSV56833104; called by muse, mutect2, varscan2
- INPP5D | c.1316C>T p.A439V (on ENST00000445964 / NM_001017915.3; = p.A438V on NM_005541.5) | Missense Mutation (SNP) | VAF 58/329 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.861); catalogued as COSV64039215; called by muse, varscan2
- KIF1B | c.5083G>A p.E1695K (on ENST00000377086 / NM_001365952.1; = p.E1649K on NM_015074.3) | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55808224; called by muse, mutect2, varscan2
- KIR2DL3 | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV100668164; called by muse, mutect2
- NIPAL4 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as rs772226292, COSV61730646; called by muse, mutect2, varscan2
- SLC2A9 | c.1018A>G p.N340D | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.992); catalogued as rs1444638664; called by muse, mutect2
- TTC6 | c.106T>C p.F36L (on ENST00000267368; = p.F1305L on NM_001310135.3) | Missense Mutation (SNP) | VAF 165/615 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs747190657; called by muse, mutect2, varscan2
- USP28 | c.2812C>T p.R938W | Missense Mutation (SNP) | VAF 114/477 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs61760223; called by muse, mutect2, varscan2
- CDH1 | c.801dup p.K268* | Frame Shift Ins (INS) | VAF 86/282 reads (30%) | called by mutect2, varscan2
- DNAH12 | c.5018G>T p.G1673V (on ENST00000351747; = p.G1696V on NM_001366028.2) | Missense Mutation (SNP) | VAF 19/452 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HNRNPA1P48 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 75/417 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA0232 | c.775T>C p.F259L | Missense Mutation (SNP) | VAF 69/520 reads (13%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRN1 | c.726G>T p.E242D | Missense Mutation (SNP) | VAF 38/664 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- MCTP2 | c.679A>G p.T227A | Missense Mutation (SNP) | VAF 28/636 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); called by muse, mutect2
- PCSK5 | c.4723G>T p.G1575W | Missense Mutation (SNP) | VAF 71/354 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- TMEM63B | c.1817A>T p.E606V | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, varscan2
- TRIM8 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 87/355 reads (25%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARD14 | c.1176G>T p.L392= | Silent (SNP) | VAF 21/302 reads (7%) | called by muse, mutect2
- ECEL1 | c.1818C>T p.I606= | Silent (SNP) | VAF 12/191 reads (6%) | catalogued as rs1284757016; called by muse, mutect2
- GDAP1 | c.840C>T p.Y280= | Silent (SNP) | VAF 30/618 reads (5%) | catalogued as rs374624466, CD149960; ClinVar: likely benign; called by muse, mutect2
- KCNJ10 | c.915C>A p.I305= | Silent (SNP) | VAF 20/578 reads (3%) | called by muse, mutect2
- LTBP4 | c.3366G>A p.P1122= (on ENST00000308370 / NM_001042544.1; = p.P1085= on NM_003573.2) | Silent (SNP) | VAF 64/424 reads (15%) | catalogued as rs371166802, COSV52578764; called by muse, mutect2, varscan2
- PCDH18 | c.1923C>T p.N641= | Silent (SNP) | VAF 54/752 reads (7%) | catalogued as rs377716033; called by muse, mutect2
- SDK2 | c.72G>T p.V24= | Silent (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- WDFY4 | c.6483G>A p.P2161= | Silent (SNP) | VAF 80/304 reads (26%) | catalogued as rs562274935, COSV55443922; called by muse, mutect2, varscan2
